Somatic mutation profile of tumor specimen TARGET-10-PARGFX-03A (aliquot TARGET-10-PARGFX-03A-01D) from TARGET case TARGET-10-PARGFX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,156 days).
Specimen TARGET-10-PARGFX-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0d47826-8097-437a-af0c-0fe5302b7cf4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARGFX-14A (Bone Marrow Normal), aliquot TARGET-10-PARGFX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84eebb8e-33ff-406d-aa5b-8d46e84a9b14

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 3, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX41 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs1479333618; called by muse, mutect2
- FAT3 | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759655557; called by muse, mutect2, varscan2
- LRP1B | c.2990G>T p.S997I | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67201386; called by muse, mutect2
- SEL1L3 | c.3274C>A p.P1092T | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs1396800390; called by muse, mutect2, varscan2
- SLC23A3 | c.1355G>A p.R452Q (on ENST00000409878 / NM_001144889.2; = p.R335Q on NM_144712.5) | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs374308076; called by muse, mutect2, varscan2
- ANKRD31 | c.626A>G p.E209G | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- ASXL3 | c.5518C>G p.Q1840E | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- ATRX | c.1466C>A p.T489N | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); called by muse, mutect2
- CADPS | c.1969G>T p.A657S | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.228); called by muse, mutect2
- DNAH9 | c.6408G>T p.Q2136H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FMO5 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- KIAA1671 | c.4328C>A p.T1443N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2
- MKRN1 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- PCDHGA8 | c.1400G>C p.R467T | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- RPRM | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- TEX14 | c.1182C>A p.N394K (on ENST00000240361 / NM_001201457.2; = p.N388K on NM_031272.5) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZNF302 | c.1396C>A p.H466N (on ENST00000627982; = p.H387N on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPM1L | c.793C>A p.R265= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- SLC7A2 | c.1410G>A p.Q470= (on ENST00000494857 / NM_001370338.1; = p.Q509= on NM_003046.6) | Silent (SNP) | VAF 66/134 reads (49%) | called by muse, mutect2, varscan2
- C7orf61 | c.63+110G>T | Intron (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- CLVS1 | c.-152+95C>T | Intron (SNP) | VAF 36/84 reads (43%) | catalogued as rs1362515540; called by muse, mutect2, varscan2
- SGCE | c.110-5211G>A | Intron (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
